Gene-level copy-number profile of tumor specimen TCGA-A2-A04Y-01A from TCGA case TCGA-A2-A04Y, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.5 years (19,533 days).
Specimen TCGA-A2-A04Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.93a1aed5-c6cc-4e07-9060-fd6cead060b2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef9b6d86-ae51-45d1-a815-1862ef65ed20

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 4,332; copy number 3: 60; copy number 4: 49,741; copy number 5: 49; copy number 6: 3,927; copy number 8: 903; copy number 9: 19; copy number 10: 153; copy number 11: 34; copy number 12: 34; copy number 14: 8; copy number 16: 4; copy number 17: 22; copy number 18: 17; copy number 19: 9; copy number 22: 9; copy number 23: 37; copy number 24: 21; copy number 25: 60; copy number 26: 32; copy number 27: 19; copy number 29: 1; copy number 30: 119; copy number 31: 11; copy number 34: 15; copy number 37: 39; copy number 39: 47; copy number 41: 19; copy number 42: 5; copy number 43: 36; copy number 60: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04Y-01A-21D-A036-01): tumor purity 0.6, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 800 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,341,385–241,677,376, 27 genes, copy number 10 (within-gene range 2–10): Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO, OPN3, CHML, AL133390.1.
- chr8:8,414,204–9,425,524, 24 genes, copy number 11 (within-gene range 2–11): AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, AC087269.3, CLDN23, AC087269.2, AC087269.1, MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2.
- chr8:9,255,349–10,859,436, 37 genes, copy number 11–37: AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2.
- chr8:78,805,293–78,956,082, 2 genes, copy number 9: AC083837.1, LINC02605.
- chr8:80,032,724–80,930,081, 28 genes, copy number 22–41: AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1.
- chr8:87,540,835–104,256,094, 310 genes, copy number 10–34 (within-gene range 6–34) (broad region; genes not listed).
- chr8:109,240,919–110,809,894, 19 genes, copy number 27: NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3.
- chr8:113,950,886–119,325,265, 38 genes, copy number 12–37: Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr8:121,380,137–133,134,903, 180 genes, copy number 9–60 (broad region; genes not listed).
- chr20:49,632,945–50,691,542, 36 genes, copy number 43 (within-gene range 4–43): B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.
- chr20:53,544,615–54,651,169, 16 genes, copy number 37 (within-gene range 2–37): Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.
- chr20:57,105,741–59,042,809, 63 genes, copy number 30 (broad region; genes not listed).
- chr20:59,352,195–60,083,872, 15 genes, copy number 24: AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1.
- chr20:60,755,001–61,083,750, 4 genes, copy number 16–29: AL117372.1, AL139348.1, AL121910.1, LINC01718.
- chr20:61,267,525–61,271,827, 1 gene, copy number 16: AL365229.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
